Somatic mutation profile of tumor specimen 0DOLVC from CCDI case PBCCTD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 5.0 years (1,808 days).
Specimen 0DOLVC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be4ac78e-60d0-4bb1-af82-c318b2d24f19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOLUU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/333a1557-df7c-4641-9f9e-b35674670af5

The open-access MAF lists 38 somatic variants for this specimen: 23 protein-altering or splice-affecting, 9 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 9, Frame Shift Ins 3, Intron 3, Nonsense Mutation 2, 3'UTR 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM6A | c.3835C>T p.R1279* | Nonsense Mutation (SNP) | VAF 182/189 reads (96%) | catalogued as rs863224886, CM162445, COSV65037841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.3694G>A p.G1232S | Missense Mutation (SNP) | VAF 167/333 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV60785813, COSV60799159; called by muse, mutect2, varscan2
- ALKBH8 | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 173/387 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs745922825; called by muse, mutect2, varscan2
- ASCC3 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 26/772 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1226193895; called by muse, mutect2
- CARD6 | c.1784T>A p.I595N | Missense Mutation (SNP) | VAF 24/508 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.112); catalogued as rs1273492433, COSV54565143; called by muse, mutect2
- DYNC1I1 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 365/548 reads (67%) | SIFT tolerated (0.81); PolyPhen benign (0.044); catalogued as rs201114371, COSV61456326; called by muse, mutect2, varscan2
- NLRP13 | c.1439G>T p.W480L | Missense Mutation (SNP) | VAF 185/355 reads (52%) | SIFT tolerated (0.54); PolyPhen benign (0.028); catalogued as COSV61621757; called by muse, mutect2
- PATJ | c.2441G>A p.G814E | Missense Mutation (SNP) | VAF 224/617 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV57162716; called by muse, mutect2, varscan2
- PLD2 | c.2159G>A p.R720H | Missense Mutation (SNP) | VAF 131/278 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1397763227, COSV54007885; called by muse, mutect2, varscan2
- TRIM64B | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 335/1539 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs761818237, COSV61694147; called by muse, mutect2, varscan2
- BAHCC1 | c.1234dup p.E412Gfs*47 | Frame Shift Ins (INS) | VAF 188/429 reads (44%) | called by mutect2, varscan2
- BAHCC1 | c.1235delinsGC p.E412Gfs*47 | Frame Shift Ins (INS) | VAF 193/626 reads (31%) | called by mutect2*, pindel, varscan2*
- CR2 | c.52dup p.V18Gfs*18 | Frame Shift Ins (INS) | VAF 109/439 reads (25%) | called by mutect2, pindel, varscan2
- LCMT1 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 183/207 reads (88%) | called by muse, mutect2, varscan2
- MYH6 | c.4255A>T p.T1419S | Missense Mutation (SNP) | VAF 368/727 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NDUFS1 | c.16G>C p.V6L | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEIL1 | c.493C>A p.L165I | Missense Mutation (SNP) | VAF 177/440 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OR2A14 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 194/609 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- PKHD1L1 | c.2991T>A p.N997K | Missense Mutation (SNP) | VAF 455/1004 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RESF1 | c.1255G>T p.D419Y | Missense Mutation (SNP) | VAF 20/436 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2
- VPS37D | c.142C>G p.Q48E | Missense Mutation (SNP) | VAF 72/777 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2
- ZNF385B | c.92A>C p.K31T | Missense Mutation (SNP) | VAF 193/402 reads (48%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- ZNF780B | c.2498G>T p.G833V | Missense Mutation (SNP) | VAF 77/463 reads (17%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMELY | c.468G>A p.Q156= (on ENST00000383036 / NM_001364814.1; = p.Q142= on NM_001143.1) | Silent (SNP) | VAF 385/408 reads (94%) | called by muse, mutect2, varscan2
- DNAH10 | c.10032A>G p.A3344= (on ENST00000409039; = p.A3283= on NM_207437.3) | Silent (SNP) | VAF 77/597 reads (13%) | called by muse, mutect2, varscan2
- EXOC7 | c.951C>T p.N317= | Silent (SNP) | VAF 318/586 reads (54%) | catalogued as rs765138832; called by muse, mutect2, varscan2
- IFI16 | c.1314C>T p.S438= | Silent (SNP) | VAF 44/685 reads (6%) | called by muse, mutect2
- PCDHGA3 | c.2190C>T p.G730= | Silent (SNP) | VAF 450/883 reads (51%) | catalogued as rs376373404; called by muse, mutect2, varscan2
- PDPR | c.2532C>T p.I844= | Silent (SNP) | VAF 24/666 reads (4%) | catalogued as rs1261693000, COSV55351583, COSV99847582; called by muse, mutect2
- SCN8A | c.4446C>T p.T1482= | Silent (SNP) | VAF 181/427 reads (42%) | catalogued as rs374059983; ClinVar: likely benign; called by muse, mutect2, varscan2
- SMPD1 | c.801C>A p.G267= | Silent (SNP) | VAF 26/338 reads (8%) | called by muse, mutect2
- ZBTB9 | c.1338G>C p.R446= | Silent (SNP) | VAF 191/551 reads (35%) | called by muse, mutect2, varscan2
- ADRM1 | c.*7C>T | 3'UTR (SNP) | VAF 28/265 reads (11%) | catalogued as rs780168002; called by muse, mutect2, varscan2
- CCL8 | c.*59C>A | 3'UTR (SNP) | VAF 58/122 reads (48%) | called by muse, mutect2, varscan2
- DOCK1 | c.1488+97C>A | Intron (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2
- PALLD | c.1965-12776G>A | Intron (SNP) | VAF 157/321 reads (49%) | catalogued as rs921512530; called by muse, mutect2, varscan2
- RPL14 | c.3+99C>A | Intron (SNP) | VAF 279/517 reads (54%) | catalogued as rs753386671; called by muse, mutect2, varscan2
- TCHHL1 | chr1:152080559 C>A | 3'Flank (SNP) | VAF 328/1141 reads (29%) | called by muse, mutect2, varscan2
